Surgical pathology report (de-identified scan), TCGA case TCGA-32-2632, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-2632-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right temporal brain tumor
2. Right temporal brain tumor

GBM
Control

CLINICAL DIAGNOSIS:

Right temporal brain tumor

TCGA-32-2632

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "right temporal brain tumor" are two pieces of tan-red soft tissue aggregating to 0.6 x 0.6 x 0.3 cm. A smear is made. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

Tissue submitted for frozen is subsequently submitted for permanent in one cassette.

2. Received in formalin labeled with the patient's name and "right temporal brain tumor" are multiple portions of tan-gray to tan-red hemorrhagic soft tissue ranging in size from 0.4 to 1.4 cm in greatest dimension. In aggregate the specimen is 2.0 x 1.4 x 0.8 cm. The specimen is entirely submitted in two cassettes.

One half of a portion of tissue is sent to

MICROSCOPIC DESCRIPTION:

- 1, 2. Sections demonstrate a markedly hypercellular glial neoplasm, the cells of which resemble atypical fibrillary astrocytes. Numerous scattered mitotic figures are seen. Microvascular proliferation is present. Confluent tumor necrosis, including pseudopalisading necrosis is noted.

DIAGNOSIS:

(PROVISIONAL):

DIAGNOSIS:

- 1, 2. RIGHT TEMPORAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

The tumor cells demonstrate patchy positivity for MGMT. Overall expression is estimated as seen in >50% of tumor cells. The sample consists of an estimated 50-75% cellular tumor.

ADDENDUM DIAGNOSIS:

- 1, 2. RIGHT TEMPORAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA
- TUMOR CELLS POSITIVE FOR MGMT EXPRESSION.

Source: NCI Genomic Data Commons file d1d2a46d-fbac-4e2a-ba87-07a6ceccd55c (TCGA-32-2632.37CD6D1C-C10E-4CA0-AD18-3D707E9B1691.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).